Surgical pathology report (de-identified scan), TCGA case TCGA-WY-A85D, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Johns Hopkins, specimen TCGA-WY-A85D-01A (Primary Tumor).

[page 1 of 6]
Patient: [REDACTED]

Path# [REDACTED]

Accessioned

Birthdate: [REDACTED]

(Age

Loc: [REDACTED]

Gender: M

Spec. Taken

=====

INTERPRETATION AND DIAGNOSIS:

1-7) BRAIN: FIBRILLARY ASTROCYTOMA, WHO GRADE II, SEE COMMENT.

COMMENT: The lesion has some oligodendroglioma qualities but also some suggesting astrocytoma lineage. Molecular studies found no evidence of loss of heterozygosity on chromosome 19q. There was and suggestive loss for 1p, but not in 2 most telometric markers. The 1p/19q codeletion was therefore not present. The MIB-1 rate is in the grade II range.

[REDACTED]

*Electronic signature

=====

GROSS DESCRIPTION

(Continued on next page.)

CCF ICD-O 3
path Oligoastrocytoma, grade II 9382/3
Astrocytoma, fibrillary, grade II (9420/3) (9400/3)
CCF Code to highest 9420/3
Site: Brain, supratentorial NOS C71.0
path Brain NOS C71.9
9/26/10/14

[page 2 of 6]
Patient: [REDACTED]

Path# [REDACTED]

[REDACTED] # [REDACTED]

Page 2

PART #1: FS: TUMOR

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

STAFF PATHOLOGIST:

OTHER PATHOLOGIST/PA:

FS: Tumor:

Dictated by: [REDACTED]

The specimen is received in saline for frozen section, labeled with the patient's name, [REDACTED], and designated 'tumor.' The specimen consists of multiple irregular fragment of white-tan to tan-pink soft tissue measuring 1.3 x 0.3 x 0.2 cm in loose aggregate. Three representative sections are submitted for frozen section, a touch prep is performed and the remainder of the specimen is submitted for routine histology.

SUMMARY OF SECTIONS

1 - FSC - 3
1 - A - MULTIPLE
2 - TOTAL - M

(Continued on next page.)

[page 3 of 6]
Patient: [REDACTED]

Path# [REDACTED]

Page 3

PART #2: FS: TUMOR #2

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists / PAs: [REDACTED]

FS Tumor #2: Lesional, consistent with infiltrating glioma.

Dictated by: [REDACTED]

The specimen is received in saline for frozen section, labeled with the patient's name, [REDACTED] and designated 'tumor #2.' The specimen consists of one irregular fragment of tan-pink soft tissue measuring 1.3 x 0.7 x 0.3 cm. A touch prep is performed. The specimen is bisected. One fragment is submitted for frozen section and the remaining fragment is submitted for routine histology.

SUMMARY OF SECTIONS

1 - FSC - 1
1 - A - 1
2 - TOTAL - 2

PART #3: TUMOR

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received in formalin, labeled with the patient's name, [REDACTED] and designated 'tumor.' The specimen consists of multiple, tiny pieces of white to yellow to pink soft tissue measuring 1.0 x 0.5 x 0.1 cm in aggregate. The entire specimen is submitted.

SUMMARY OF SECTIONS

(Continued on next page.)

[page 4 of 6]
Patient: [REDACTED]

Path# [REDACTED]

[REDACTED] # [REDACTED]

Page 4

=====

1 - A - MULTIPLE (SOFT TISSUE)
1 - TOTAL - M

PART #4: ANTERIOR ASPECT

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received in formalin, labeled with the patient's name, [REDACTED] and designated 'anterior aspect.' The specimen consists of multiple, tiny pieces of irregular, white to yellow to pink soft tissue measuring 0.5 x 0.5 x 0.1 cm in aggregate. The entire specimen is submitted in a bag.

SUMMARY OF SECTIONS

1 - A - MULTIPLE (SOFT TISSUE)
1 - TOTAL - M

PART #5: TUMOR VIA

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received in formalin, labeled with the patient's name, [REDACTED] and designated 'tumor via [REDACTED]'. The specimen consists of multiple, tiny pieces of white to pink soft tissue measuring 2.0 x 2.0 x 0.1 cm in aggregate. The entire specimen is submitted in a bag.

SUMMARY OF SECTIONS

1 - A - MULTIPLE (SOFT TISSUE)
1 - TOTAL - M

(Continued on next page.)

[page 5 of 6]
Patient: [REDACTED]

Path# [REDACTED]

Page 5

PART #6: POSTERIOR INFERIOR ASPECT

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received in formalin, labeled with the patient's name, [REDACTED], and designated 'posterior inferior aspect.' The specimen consists of two pieces of irregular, unoriented white to pink soft tissue measuring 2.5 x 1.0 x 0.2 cm in aggregate. The entire specimen is submitted in lens paper.

SUMMARY OF SECTIONS

- 1 - A - 2 (SOFT TISSUE)
- 1 - TOTAL - 2

PART #7: POSTERIOR SUPERIOR ASPECT

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received in formalin, labeled with the patient's name, [REDACTED], and designated 'posterior superior aspect.' The specimen consists of an irregular piece unoriented, white to pink soft tissue measuring 0.5 x 0.5 x 0.2 cm. The entire specimen is submitted in lens paper.

SUMMARY OF SECTIONS

- 1 - A - 1 (SOFT TISSUE)
- 1 - TOTAL - 1

Other Surgical Pathology Specimens known to the computer: [REDACTED]

(End of Report)

printed

*Per TSS, dx discrepancy from
state re: tumor to be
oligoastrocytoma, grade II.*

Unilateral/Synchronous Primary Tumor		✓
are is (circle):	DISQUALIFIED	DISQUALIFIED

[page 6 of 6]
TCGA Pathologic Diagnosis Discrepancy Form 4.05 ☒

Study Subject ID:

Study/Site: TCGA Brain lower grade glioma -

Event: PathDiscrepancy

Interviewer:

Person ID: N/A

Age: N/A

Date of Birth:

Sex: M

**Tumor Identifier Provided on Initial Case
Quality Control Form**

Provide the tumor identifier documented on the initial case quality control form for this case.

**Pathologic Diagnosis Provided
on Initial Pathology Report** astrocytoma,
Grade II

Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

**Histologic features of the sample provided
for TCGA, as reflected on the CQCF** oligoastrocytoma,
Grade II

Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

**Provide the reason for the
discrepancy between the
pathology report and the TCGA
Case Quality Control Form**

original diagnosis was astrocytoma, Grade II.
Upon further analysis, this tumor was found to
have a mixed component and was reclassified as
an oligoastrocytoma, Grade II.

Provide a reason describing why the
diagnosis on the initial pathology report for
this case is not consistent with the diagnosis
selected on the TCGA Case Quality Control
Form.

**Name of TSS Reviewing Pathologist or Biorepository
Director** Dr.

Provide the name of the pathologist who reviewed this case
for TCGA.

Source: NCI Genomic Data Commons file cf8b55f7-efbd-4b49-b298-03f7c45f26fc (TCGA-WY-A85D.82FFEB3D-5C1C-4FF0-A824-5C24F3B82B3C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).